Somatic mutation profile of tumor specimen TARGET-20-PATDMY-09A (aliquot TARGET-20-PATDMY-09A-01D) from TARGET case TARGET-20-PATDMY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,760 days).
Specimen TARGET-20-PATDMY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49444755-8995-4f18-8554-a7f204dfc598.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDMY-14A (Bone Marrow Normal), aliquot TARGET-20-PATDMY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343a35e1-3629-4523-b34e-fecdf7a9cfbf

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV56765411, COSV56765443; called by muse, mutect2, varscan2
- MYH11 | c.753C>A p.D251E | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs775577319; called by muse, mutect2, varscan2
